Gene-level copy-number profile of tumor specimen HCM-BROD-0027-C34-06A from HCMI case HCM-BROD-0027-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.4 years (23,897 days).
Specimen HCM-BROD-0027-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a087139a-0a64-4ab7-b92d-54f141bbe7c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0027-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/e4f7a58d-fec5-44b8-9aa2-a7c2cd9f6957

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 19,821; copy number 2: 34,023; copy number 3: 4,449; copy number 4: 61; copy number 5: 15; copy number 6: 9; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:8,981,436–8,990,806, 2 genes: AC073648.3, AC073648.2.
- chr5:59,314,110–59,703,703, 3 genes (within-gene range 0–1): AC008833.1, NDUFB4P2, MIR582.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:39,734,670–39,810,097, 4 genes: RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–1): BX664615.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,361,820–18,391,105, 2 genes, copy number 6: FAM230J, AC011718.1.
- chr22:18,486,999–18,491,247, 1 gene, copy number 9 (within-gene range 1–9): AC023490.2.

Autosomal genes at a single copy (total copy number 1): 19,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
